Somatic mutation profile of tumor specimen ALCH-AELP-TTP1-A (aliquot ALCH-AELP-TTP1-A-1-0-D-A627-36) from ALCHEMIST case ALCH-AELP, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 69.6 years (25,428 days).
Specimen ALCH-AELP-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b09f29e7-fa79-4d8c-849d-37805a63227f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AELP-NB1-A (Blood Derived Normal), aliquot ALCH-AELP-NB1-A-1-0-D-A628-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bbbfe0de-3af4-4c18-95e0-778b5fe776eb

The open-access MAF lists 62 somatic variants for this specimen: 45 protein-altering or splice-affecting, 11 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 11, Nonsense Mutation 3, Splice Site 2, RNA 2, Frame Shift Ins 2, 3'UTR 2, In Frame Ins 1, 5'Flank 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2317_2319dup p.H773dup | In Frame Ins (INS) | VAF 244/494 reads (49%) | hotspot (GDC flag); catalogued as rs1554350381, COSV51800933, COSV51820458; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- TP53 | c.372C>A p.C124* | Nonsense Mutation (SNP) | VAF 32/160 reads (20%) | catalogued as rs1555526478, CM1210346, COSV52731101, COSV52944837; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BRINP2 | c.1130C>A p.A377D | Missense Mutation (SNP) | VAF 67/563 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV100838100; called by muse, mutect2, varscan2
- CPED1 | c.34C>T p.R12* | Nonsense Mutation (SNP) | VAF 17/245 reads (7%) | catalogued as COSV59997510; called by muse, mutect2
- CSF1R | c.685G>A p.V229I | Missense Mutation (SNP) | VAF 30/375 reads (8%) | SIFT tolerated (0.47); PolyPhen benign (0.011); catalogued as rs149911279, COSV53830159, COSV53833326; called by muse, mutect2
- DLGAP2 | c.230C>T p.A77V | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.007); catalogued as rs1356764415, COSV101421527; called by muse, varscan2
- DOCK4 | c.340C>T p.R114W | Missense Mutation (SNP) | VAF 35/190 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.462); catalogued as rs752637866; called by muse, mutect2, varscan2
- ESRP1 | c.712G>T p.D238Y | Missense Mutation (SNP) | VAF 104/367 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64411002; called by muse, mutect2, varscan2
- FMN2 | c.2309C>T p.P770L | Missense Mutation (SNP) | VAF 30/344 reads (9%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as rs368527329; called by muse, mutect2
- FOXRED1 | c.94G>A p.G32R | Missense Mutation (SNP) | VAF 42/536 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.05); catalogued as rs755584797; called by muse, mutect2
- GBA2 | c.2122G>A p.A708T | Missense Mutation (SNP) | VAF 12/262 reads (5%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs1483562952; called by muse, mutect2
- HLA-DQA2 | c.746C>A p.S249Y | Missense Mutation (SNP) | VAF 69/464 reads (15%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.896); catalogued as COSV66566307; called by muse, mutect2, varscan2
- KIF4B | c.490C>T p.R164W | Missense Mutation (SNP) | VAF 77/715 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs200058266; called by muse, mutect2, varscan2
- KRT20 | c.982C>A p.L328I | Missense Mutation (SNP) | VAF 90/399 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV51426146; called by muse, mutect2, varscan2
- MYT1 | c.1124G>T p.R375L | Missense Mutation (SNP) | VAF 62/294 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV60515893; called by mutect2, varscan2
- NAV2 | c.5296G>T p.A1766S (on ENST00000396087 / NM_001244963.2; = p.A1710S on NM_145117.5) | Missense Mutation (SNP) | VAF 79/408 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as rs1193952008; called by muse, mutect2, varscan2
- OR1Q1 | c.814C>T p.R272C | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as rs1397350258, COSV52918020, COSV52919601; called by muse, mutect2, varscan2
- OR2G2 | c.703A>C p.T235P | Missense Mutation (SNP) | VAF 63/264 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.359); catalogued as COSV60741587; called by muse, mutect2, varscan2
- PCDHB6 | c.1825G>T p.E609* | Nonsense Mutation (SNP) | VAF 52/382 reads (14%) | catalogued as rs1238666935; called by muse, mutect2, varscan2
- PRICKLE2 | c.638C>T p.P213L (on ENST00000295902; = p.P157L on NM_198859.4) | Missense Mutation (SNP) | VAF 45/407 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55773766; called by muse, mutect2, varscan2
- TP53 | c.371G>A p.C124Y | Missense Mutation (SNP) | VAF 31/159 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.172); catalogued as COSV52850044, COSV52897973, COSV53107967; called by muse, mutect2, varscan2
- TRIM31 | c.679G>A p.D227N | Missense Mutation (SNP) | VAF 31/418 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.32); catalogued as rs761494388, COSV100946731; called by muse, mutect2
- WDR64 | c.1556C>T p.A519V | Missense Mutation (SNP) | VAF 23/332 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs779492445, COSV63798197; called by muse, mutect2
- ZNF598 | c.442C>T p.R148C | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); catalogued as rs368327489; called by muse, mutect2, varscan2
- ZNF844 | c.1079G>T p.R360I | Missense Mutation (SNP) | VAF 36/188 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.326); catalogued as COSV101462794; called by muse, mutect2, varscan2
- ADAMTSL1 | c.989A>T p.N330I | Missense Mutation (SNP) | VAF 22/250 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.602); called by muse, mutect2
- AK5 | c.416-1G>A p.X139_splice (on ENST00000354567 / NM_174858.3; = p.X113_splice on NM_012093.4) | Splice Site (SNP) | VAF 20/159 reads (13%) | called by muse, mutect2, varscan2
- BTNL3 | c.940G>T p.A314S | Missense Mutation (SNP) | VAF 48/337 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- CCNJL | c.586G>C p.A196P | Missense Mutation (SNP) | VAF 73/388 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CSMD3 | c.2429A>T p.E810V (on ENST00000297405 / NM_001363185.1; = p.E706V on NM_052900.3) | Missense Mutation (SNP) | VAF 69/314 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DENND5A | c.1592A>G p.Y531C | Missense Mutation (SNP) | VAF 51/677 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FAM209A | c.511A>G p.S171G | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.055); called by muse, mutect2
- FANK1 | c.936A>T p.K312N | Missense Mutation (SNP) | VAF 83/391 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- FGD4 | c.2252dup p.A752Sfs*5 | Frame Shift Ins (INS) | VAF 69/462 reads (15%) | called by mutect2, pindel, varscan2
- GVQW3 | c.167A>G p.D56G | Missense Mutation (SNP) | VAF 44/329 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- KIAA0319L | c.2803A>G p.I935V | Missense Mutation (SNP) | VAF 49/520 reads (9%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.577); called by muse, mutect2
- KLHL18 | c.826T>G p.F276V | Missense Mutation (SNP) | VAF 52/275 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- PIWIL1 | c.2498A>T p.Q833L | Missense Mutation (SNP) | VAF 92/350 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- POTEG | c.1019C>A p.T340K | Missense Mutation (SNP) | VAF 124/1430 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); called by muse, varscan2
- SON | c.1408C>T p.P470S | Missense Mutation (SNP) | VAF 56/231 reads (24%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- TRAP1 | c.1413dup p.S472Vfs*44 | Frame Shift Ins (INS) | VAF 47/263 reads (18%) | called by mutect2, pindel, varscan2
- TTC12 | c.1267G>T p.A423S | Missense Mutation (SNP) | VAF 27/254 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TUB | c.254-1G>C p.X85_splice (on ENST00000299506 / NM_177972.3; = p.X140_splice on NM_003320.4) | Splice Site (SNP) | VAF 38/422 reads (9%) | called by muse, mutect2
- UHRF1BP1 | c.2102T>G p.I701S | Missense Mutation (SNP) | VAF 37/320 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.374); called by muse, mutect2, varscan2
- WWC2 | c.2641G>A p.E881K | Missense Mutation (SNP) | VAF 64/444 reads (14%) | SIFT tolerated (0.91); PolyPhen benign (0.003); called by muse, varscan2
- CDK13 | c.3459G>A p.S1153= | Silent (SNP) | VAF 104/500 reads (21%) | catalogued as rs778552078, COSV51698073; called by muse, mutect2, varscan2
- ITGAL | c.3222G>C p.L1074= | Silent (SNP) | VAF 66/298 reads (22%) | called by muse, mutect2, varscan2
- KDM2A | c.2685G>T p.R895= | Silent (SNP) | VAF 8/27 reads (30%) | called by muse, mutect2, varscan2
- LZTS1 | c.1488C>T p.D496= | Silent (SNP) | VAF 18/94 reads (19%) | catalogued as rs370252646; called by muse, mutect2, varscan2
- MS4A3 | c.31C>T p.L11= | Silent (SNP) | VAF 33/131 reads (25%) | called by muse, mutect2, varscan2
- MTFMT | c.495C>T p.H165= | Silent (SNP) | VAF 32/394 reads (8%) | catalogued as rs752555152; called by muse, mutect2
- OR4D9 | c.867G>A p.L289= | Silent (SNP) | VAF 18/260 reads (7%) | catalogued as COSV61434833; called by muse, mutect2
- RYR2 | c.1941T>C p.R647= | Silent (SNP) | VAF 78/412 reads (19%) | called by muse, mutect2, varscan2
- SYT6 | c.690C>T p.C230= (on ENST00000610222 / NM_001366225.1; = p.C145= on NM_205848.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 46/498 reads (9%) | catalogued as rs370907546; called by muse, mutect2
- TNR | c.246G>A p.G82= | Silent (SNP) | VAF 39/368 reads (11%) | catalogued as COSV54911778; called by muse, mutect2, varscan2
- TWF1 | c.321T>A p.T107= | Silent (SNP) | VAF 94/460 reads (20%) | called by muse, mutect2, varscan2
- AL512625.1 | n.259C>A | RNA (SNP) | VAF 22/338 reads (7%) | catalogued as rs7018555; called by muse, mutect2
- EFEMP2 | c.161-28del | Intron (DEL) | VAF 12/120 reads (10%) | catalogued as COSV100337189; called by mutect2, varscan2
- MEX3D | c.*168C>T | 3'UTR (SNP) | VAF 33/127 reads (26%) | called by muse, mutect2, varscan2
- SNORA60 | n.28G>T | RNA (SNP) | VAF 51/303 reads (17%) | called by muse, mutect2, varscan2
- TTYH1 | c.*72A>C | 3'UTR (SNP) | VAF 20/96 reads (21%) | called by muse, mutect2, varscan2
- WT1 | chr11:32438556 T>A | 5'Flank (SNP) | VAF 26/248 reads (10%) | called by muse, mutect2, varscan2
